Somatic mutation profile of tumor specimen MP2PRT-PAUNIX-TMP1-A (aliquot MP2PRT-PAUNIX-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUNIX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,709 days).
Specimen MP2PRT-PAUNIX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b64f6fff-c38e-44fb-a9e0-29c03fc45228.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNIX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNIX-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7539b204-4f7e-4898-9447-2db28a121f19

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 122/366 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs121913644, CM011799; ClinVar: pathogenic / uncertain significance / likely benign; called by muse, mutect2, varscan2
- ABCA6 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 111/426 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.123); catalogued as rs372285217; called by muse, mutect2, varscan2
- FAM83H | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 242/1113 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs137854442, CM093736, COSV66354661; called by muse, mutect2, varscan2
- MRGPRX1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 97/458 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs767184906, COSV57106940; called by muse, mutect2
- PCDHA6 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 105/383 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV65352427; called by muse, mutect2, varscan2
- UNC45B | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 128/498 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749498469; called by muse, mutect2, varscan2
- FLT3 | c.1780_1793delinsCC p.F594_E598delinsP | In Frame Del (DEL) | VAF 74/304 reads (24%) | called by pindel, varscan2*
- GASK1B | c.1293G>T p.K431N | Missense Mutation (SNP) | VAF 99/523 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- MATN4 | c.1001G>A p.R334K (on ENST00000372754; = p.R293K on NM_003833.4) | Missense Mutation (SNP) | VAF 69/220 reads (31%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH9 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 102/487 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2
- PDZD4 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 227/605 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf68 | c.393G>A p.T131= | Silent (SNP) | VAF 171/636 reads (27%) | catalogued as rs753395174; called by muse, mutect2, varscan2
- DACT3 | c.906G>A p.A302= | Silent (SNP) | VAF 162/499 reads (32%) | called by muse, mutect2, varscan2
- MYOM1 | c.174C>T p.S58= | Silent (SNP) | VAF 54/1086 reads (5%) | catalogued as rs561558047, COSV55299307; called by muse, mutect2
